Somatic mutation profile of tumor specimen ALCH-B3BH-TTP1-A (aliquot ALCH-B3BH-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3BH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.5 years (21,380 days).
Specimen ALCH-B3BH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ad32938-3d6a-49ba-9cdc-5a003930714b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3BH-NB1-A (Blood Derived Normal), aliquot ALCH-B3BH-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d0046ec-a4cb-4127-b24f-375f2a070102

The open-access MAF lists 466 somatic variants for this specimen: 321 protein-altering or splice-affecting, 85 silent, 60 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 274, Silent 85, Intron 28, Nonsense Mutation 17, RNA 16, Frame Shift Del 12, Frame Shift Ins 8, Splice Site 8, 5'UTR 6, 3'UTR 5, 3'Flank 3, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1A | c.4532C>A p.A1511D | Missense Mutation (SNP) | VAF 34/286 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064794629; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KIT | c.2458G>T p.D820Y | Missense Mutation (SNP) | VAF 531/839 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519710, CM023092, COSV55387253, COSV55397865, COSV55435132; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STK11 | c.842del p.P281Rfs*6 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs121913321; ClinVar: pathogenic; called by mutect2, pindel
- TP53 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 61/171 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1555526131, COSV52674926, COSV52693942, COSV52759722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRL4 | c.1166G>A p.C389Y | Missense Mutation (SNP) | VAF 29/284 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367951491; called by muse, mutect2, varscan2
- ANK3 | c.5995G>T p.E1999* | Nonsense Mutation (SNP) | VAF 23/176 reads (13%) | catalogued as COSV55052178; called by muse, mutect2, varscan2
- ANO3 | c.692G>T p.R231M | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56805026; called by muse, mutect2, varscan2
- ARMC8 | c.314A>G p.H105R (on ENST00000469044 / NM_001363941.2; = p.H91R on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs1403169056; called by muse, varscan2
- ATG16L1 | c.157G>T p.A53S | Missense Mutation (SNP) | VAF 58/443 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.02); catalogued as rs373586724; called by muse, mutect2, varscan2
- ATP1A3 | c.585G>T p.E195D (on ENST00000545399 / NM_001256214.2; = p.E182D on NM_152296.5) | Missense Mutation (SNP) | VAF 35/316 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV100132391; called by muse, mutect2, varscan2
- ATP6V0A2 | c.806G>T p.R269L | Missense Mutation (SNP) | VAF 68/552 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100376830; called by muse, mutect2, varscan2
- AVPR1A | c.1057G>A p.G353S | Missense Mutation (SNP) | VAF 34/410 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.831); catalogued as COSV100146869; called by muse, mutect2
- BCL11B | c.1339C>A p.R447S (on ENST00000357195 / NM_001282237.2; = p.R376S on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61734668; called by muse, mutect2, varscan2
- BTNL9 | c.622C>A p.L208M | Missense Mutation (SNP) | VAF 89/484 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59793507; called by muse, mutect2, varscan2
- CACHD1 | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 49/465 reads (11%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.956); catalogued as rs1332057927; called by muse, mutect2, varscan2
- CCT6B | c.637G>T p.D213Y | Missense Mutation (SNP) | VAF 43/261 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774461219; called by muse, mutect2, varscan2
- CDH9 | c.1512+1G>T p.X504_splice | Splice Site (SNP) | VAF 89/220 reads (40%) | catalogued as COSV50257314; called by muse, mutect2, varscan2
- CNTNAP2 | c.2401G>T p.A801S | Missense Mutation (SNP) | VAF 42/531 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV62162735; called by muse, mutect2
- COL28A1 | c.829G>C p.G277R | Missense Mutation (SNP) | VAF 24/548 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101258422; called by muse, mutect2
- COL7A1 | c.8752C>A p.R2918S | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56477167; called by muse, mutect2, varscan2
- CRP | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 54/263 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs34340208; called by muse, mutect2, varscan2
- DCAF8L1 | c.841C>A p.R281S | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.317); catalogued as COSV71595366, COSV71595372; called by muse, mutect2, varscan2
- DNAH7 | c.2549G>T p.R850L | Missense Mutation (SNP) | VAF 52/264 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV100418200; called by muse, mutect2, varscan2
- DNAJC13 | c.3026G>C p.C1009S | Missense Mutation (SNP) | VAF 56/658 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1334872643; called by muse, mutect2
- DRP2 | c.1177G>T p.A393S | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV100871916; called by muse, mutect2, varscan2
- DUOX2 | c.1265G>A p.R422H | Missense Mutation (SNP) | VAF 44/367 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201135069; called by muse, mutect2, varscan2
- EDN3 | c.488G>A p.G163E | Missense Mutation (SNP) | VAF 108/511 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1200963410; called by muse, mutect2, varscan2
- EWSR1 | c.1433G>A p.G478E | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as rs1431048672; called by muse, mutect2, varscan2
- FAT3 | c.10115C>A p.P3372H | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.698); catalogued as COSV53185921; called by muse, mutect2, varscan2
- FBN3 | c.4531G>A p.G1511R | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375346374, COSV99561302; called by muse, mutect2, varscan2
- FOCAD | c.1921-1G>T p.X641_splice | Splice Site (SNP) | VAF 20/116 reads (17%) | catalogued as COSV58103701; called by muse, mutect2, varscan2
- GAB4 | c.986C>A p.P329H | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV68753225; called by muse, mutect2, varscan2
- GDNF | c.11G>T p.W4L | Missense Mutation (SNP) | VAF 93/267 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1057470892; called by muse, mutect2, varscan2
- GNAT1 | c.256A>G p.T86A | Missense Mutation (SNP) | VAF 45/355 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.024); catalogued as rs1338199628; called by muse, mutect2, varscan2
- GPC6 | c.1600C>T p.R534C | Missense Mutation (SNP) | VAF 75/555 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.657); catalogued as rs780892208; called by muse, mutect2, varscan2
- GRAMD1C | c.1634-2A>G p.X545_splice | Splice Site (SNP) | VAF 49/295 reads (17%) | catalogued as COSV63982675; called by muse, mutect2, varscan2
- GRIA2 | c.1014G>T p.W338C | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV52382975; called by muse, mutect2, varscan2
- GRM5 | c.507G>C p.Q169H | Missense Mutation (SNP) | VAF 41/239 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59590046, COSV59605619, COSV59635312; called by muse, mutect2, varscan2
- H2BC6 | c.187A>G p.M63V | Missense Mutation (SNP) | VAF 127/701 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.487); catalogued as rs1334779520; called by muse, mutect2, varscan2
- HACL1 | c.280G>C p.G94R | Missense Mutation (SNP) | VAF 82/411 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781735136; called by muse, mutect2, varscan2
- HHLA1 | c.977G>A p.W326* | Nonsense Mutation (SNP) | VAF 41/392 reads (10%) | catalogued as rs781124073; called by muse, mutect2, varscan2
- HIP1R | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 33/208 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746265607; called by muse, mutect2, varscan2
- IFNA16 | c.482C>A p.P161H | Missense Mutation (SNP) | VAF 67/401 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as COSV66510139; called by muse, mutect2, varscan2
- IL2RA | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 36/227 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV56920978; called by muse, mutect2, varscan2
- INSL5 | c.104G>T p.R35L | Missense Mutation (SNP) | VAF 21/216 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV58788176; called by muse, mutect2, varscan2
- ITGA2 | c.520G>T p.D174Y | Missense Mutation (SNP) | VAF 111/542 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99671754; called by muse, mutect2, varscan2
- KCNJ12 | c.5C>A p.T2N | Missense Mutation (SNP) | VAF 19/306 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs782114975; called by muse, mutect2
- KEL | c.1915G>T p.V639F | Missense Mutation (SNP) | VAF 82/547 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as COSV100787038; called by muse, mutect2, varscan2
- KIF16B | c.371G>T p.R124L | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1478305353, COSV61705892; called by muse, mutect2, varscan2
- KRT40 | c.687G>T p.E229D | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as COSV66696686; called by muse, mutect2, varscan2
- KRT6A | c.719G>C p.R240T | Missense Mutation (SNP) | VAF 28/425 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as rs1018207300; called by muse, mutect2
- LMTK2 | c.104-1G>T p.X35_splice | Splice Site (SNP) | VAF 23/117 reads (20%) | catalogued as COSV52006310; called by muse, mutect2, varscan2
- LRFN5 | c.799C>A p.P267T | Missense Mutation (SNP) | VAF 41/521 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV53250844; called by muse, mutect2
- LRRC7 | c.2188C>T p.P730S (on ENST00000651989 / NM_001370785.2; = p.P697S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/372 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as rs1460807529, COSV50437690; called by muse, mutect2, varscan2
- METTL4 | c.401G>T p.R134L | Missense Mutation (SNP) | VAF 26/227 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV60603940; called by muse, mutect2, varscan2
- MORC3 | c.1673G>A p.R558K | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs767068699; called by muse, mutect2
- MUC16 | c.27703C>A p.H9235N | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.246); catalogued as rs373118423; called by muse, mutect2, varscan2
- MYH11 | c.1027C>G p.Q343E | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.226); catalogued as COSV55555943; called by muse, mutect2, varscan2
- NAALADL2 | c.655G>T p.V219L | Missense Mutation (SNP) | VAF 125/652 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs918709802; called by muse, mutect2, varscan2
- NAV3 | c.5036C>A p.A1679D | Missense Mutation (SNP) | VAF 36/452 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV57096042; called by muse, mutect2
- NELL2 | c.277C>G p.L93V | Missense Mutation (SNP) | VAF 26/322 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as rs747778467, COSV61587889; called by muse, mutect2
- NLRP1 | c.1261G>T p.E421* | Nonsense Mutation (SNP) | VAF 63/333 reads (19%) | catalogued as COSV99332767; called by muse, mutect2, varscan2
- NLRP4 | c.332G>A p.W111* | Nonsense Mutation (SNP) | VAF 22/257 reads (9%) | catalogued as COSV100016957, COSV56721318; called by muse, mutect2
- NTRK1 | c.2228G>T p.G743V | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1431206237, COSV62324602; called by muse, mutect2, varscan2
- NTSR2 | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.018); catalogued as rs369671796; called by muse, mutect2
- OR10D3 | c.467C>A p.S156Y | Missense Mutation (SNP) | VAF 64/455 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV100591112; called by muse, mutect2, varscan2
- OR10J5 | c.166C>A p.H56N | Missense Mutation (SNP) | VAF 46/236 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV58387166; called by muse, mutect2, varscan2
- OR11H6 | c.545C>G p.S182C | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as COSV100209949, COSV59644073; called by muse, mutect2
- OR1B1 | c.834G>T p.M278I | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.474); catalogued as COSV100506451, COSV59171900; called by muse, mutect2, varscan2
- OR2F2 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 59/263 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752154956, COSV101283815; called by muse, mutect2, varscan2
- OR2M4 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 54/321 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); catalogued as COSV60709988; called by muse, mutect2, varscan2
- OR2M5 | c.293C>A p.A98D | Missense Mutation (SNP) | VAF 76/476 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV63545928; called by muse, mutect2, varscan2
- OR2T1 | c.688G>T p.V230L | Missense Mutation (SNP) | VAF 58/263 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV100822239; called by muse, mutect2, varscan2
- OR51Q1 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs200984341; called by muse, mutect2
- OR5B17 | c.317C>A p.A106D | Missense Mutation (SNP) | VAF 48/197 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV100641986; called by muse, mutect2, varscan2
- OR8D2 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 10/133 reads (8%) | catalogued as COSV100658937; called by muse, mutect2
- OSBPL3 | c.1784C>G p.S595C | Missense Mutation (SNP) | VAF 26/270 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as COSV57658401; called by muse, mutect2
- PAK4 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 97/195 reads (50%) | catalogued as COSV58946128; called by muse, mutect2, varscan2
- PBX1 | c.1048G>T p.V350L | Missense Mutation (SNP) | VAF 48/318 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV63345179; called by muse, mutect2, varscan2
- PCDH15 | c.4054C>G p.L1352V | Missense Mutation (SNP) | VAF 45/379 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.541); catalogued as COSV104411497; called by muse, mutect2, varscan2
- PCDHA11 | c.1912G>T p.E638* | Nonsense Mutation (SNP) | VAF 14/182 reads (8%) | catalogued as rs1554164977, COSV100251830; called by muse, mutect2
- PCDHB14 | c.163G>T p.G55W | Missense Mutation (SNP) | VAF 56/349 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.886); catalogued as COSV53387071; called by muse, mutect2, varscan2
- PCMTD2 | c.796A>C p.K266Q | Missense Mutation (SNP) | VAF 67/474 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.197); catalogued as rs138454812; called by muse, mutect2, varscan2
- PELI2 | c.593del p.G198Afs*73 | Frame Shift Del (DEL) | VAF 22/129 reads (17%) | catalogued as COSV50713636; called by mutect2, pindel, varscan2
- PTPN5 | c.1626C>A p.C542* | Nonsense Mutation (SNP) | VAF 39/188 reads (21%) | catalogued as COSV60037775; called by muse, mutect2, varscan2
- RAX | c.218G>T p.C73F | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1389571436; called by muse, varscan2
- RUNX1T1 | c.797G>T p.R266L (on ENST00000265814 / NM_001198628.1; = p.R239L on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 158/464 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99750353; called by muse, mutect2, varscan2
- RYR1 | c.11609G>A p.G3870E | Missense Mutation (SNP) | VAF 25/559 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs1249167528; called by muse, mutect2
- SCIN | c.2088G>T p.Q696H (on ENST00000297029 / NM_001112706.3; = p.Q449H on NM_033128.3) | Missense Mutation (SNP) | VAF 40/335 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201987769; called by muse, mutect2, varscan2
- SEMA5A | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 110/807 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs752401925; called by muse, mutect2, varscan2
- SHROOM1 | c.2383G>T p.G795C (on ENST00000378679 / NM_001172700.2; = p.G790C on NM_133456.2) | Missense Mutation (SNP) | VAF 65/261 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV104409926; called by muse, mutect2, varscan2
- SLC35F5 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 39/279 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs780054626, COSV55517062; called by muse, mutect2, varscan2
- SLFN5 | c.1234C>A p.R412S | Missense Mutation (SNP) | VAF 32/251 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as rs763472910, COSV55481879; called by muse, mutect2, varscan2
- SORL1 | c.2888C>G p.P963R | Missense Mutation (SNP) | VAF 53/216 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99495246; called by muse, mutect2, varscan2
- SPDL1 | c.468G>C p.Q156H | Missense Mutation (SNP) | VAF 72/382 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs570031255; called by muse, mutect2, varscan2
- SPEF2 | c.3569G>C p.R1190P | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61549353; called by muse, mutect2, varscan2
- TAS2R50 | c.778G>T p.V260F | Missense Mutation (SNP) | VAF 95/537 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.139); catalogued as COSV67856449; called by muse, mutect2, varscan2
- TLR4 | c.1934C>A p.S645Y (on ENST00000355622 / NM_138554.5; = p.S605Y on NM_003266.4) | Missense Mutation (SNP) | VAF 48/230 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.284); catalogued as rs560472197, COSV100842621; called by muse, mutect2, varscan2
- TMEM132C | c.2466C>A p.S822R | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as COSV59425572; called by muse, mutect2, varscan2
- TMEM273 | c.260G>T p.R87I | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV100939710; called by muse, mutect2, varscan2
- TMPRSS15 | c.1402A>G p.T468A | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99519236; called by muse, mutect2, varscan2
- TSHZ1 | c.2175C>G p.N725K (on ENST00000580243 / NM_001308210.2; = p.N680K on NM_005786.6) | Missense Mutation (SNP) | VAF 43/203 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.471); catalogued as COSV59009816; called by muse, mutect2, varscan2
- TSKS | c.400-1G>T p.X134_splice | Splice Site (SNP) | VAF 15/94 reads (16%) | catalogued as COSV55876422; called by muse, mutect2, varscan2
- UNC13C | c.3072G>T p.G1024= | Splice Region (SNP) | VAF 70/273 reads (26%) | catalogued as COSV52861622; called by muse, mutect2, varscan2
- UPF3A | c.599G>T p.G200V | Missense Mutation (SNP) | VAF 59/241 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs754474639, COSV100677787; called by muse, mutect2, varscan2
- USH2A | c.2009G>C p.G670A | Missense Mutation (SNP) | VAF 34/240 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as rs1479691631; called by muse, mutect2, varscan2
- VPS13B | c.2912G>T p.R971L | Missense Mutation (SNP) | VAF 43/598 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.614); catalogued as COSV62149590, COSV62157058; called by muse, mutect2
- XIRP2 | c.770G>T p.S257I (on ENST00000628543; = p.S432I on NM_152381.6) | Missense Mutation (SNP) | VAF 35/325 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.133); catalogued as COSV99744427; called by muse, mutect2, varscan2
- ZC3H4 | c.2543G>T p.R848L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53412831; called by muse, mutect2, varscan2
- ZFHX4 | c.3199C>G p.R1067G | Missense Mutation (SNP) | VAF 146/536 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867525228, COSV99263455; called by muse, mutect2, varscan2
- ZMYM1 | c.2717A>G p.D906G | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV63253762; called by muse, varscan2
- ZMYM2 | c.1981C>T p.Q661* | Nonsense Mutation (SNP) | VAF 13/74 reads (18%) | catalogued as COSV67037226; called by muse, mutect2, varscan2
- ZNF716 | c.961G>T p.E321* | Nonsense Mutation (SNP) | VAF 41/483 reads (8%) | catalogued as COSV70783357; called by muse, mutect2
- ZNF773 | c.842G>T p.G281V | Missense Mutation (SNP) | VAF 41/376 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56588318; called by muse, mutect2, varscan2
- ZNF804A | c.3056C>A p.T1019K | Missense Mutation (SNP) | VAF 42/235 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs200513295; called by muse, mutect2, varscan2
- ADGRG7 | c.434C>A p.T145N | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADRA2B | c.1304G>T p.R435L | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- AHNAK2 | c.5168A>T p.N1723I | Missense Mutation (SNP) | VAF 40/305 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- AKAP9 | c.7831C>T p.Q2611* (on ENST00000359028; = p.Q2587* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 47/205 reads (23%) | called by muse, mutect2, varscan2
- ALDH4A1 | c.298A>T p.S100C | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- ALKBH8 | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2
- ALLC | c.142G>C p.G48R | Missense Mutation (SNP) | VAF 44/329 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ALX1 | c.172C>A p.R58S | Missense Mutation (SNP) | VAF 58/224 reads (26%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); called by mutect2, varscan2
- ANKRD30A | c.488C>A p.A163E (on ENST00000611781; = p.A107E on NM_052997.2) | Missense Mutation (SNP) | VAF 38/254 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ANKRD33B | c.994C>G p.P332A | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ANLN | c.295A>T p.S99C | Missense Mutation (SNP) | VAF 64/636 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.379); called by muse, mutect2
- ANO3 | c.1022del p.P341Hfs*43 | Frame Shift Del (DEL) | VAF 52/325 reads (16%) | called by mutect2, pindel, varscan2
- ARHGAP32 | c.501G>T p.W167C | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- ARHGEF26 | c.1031T>C p.L344P | Missense Mutation (SNP) | VAF 40/282 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ARMC8 | c.221_222delinsG p.T74Sfs*6 (on ENST00000469044 / NM_001363941.2; = p.T60Sfs*6 on NM_014154.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 48/275 reads (17%) | called by pindel, varscan2*
- ASPM | c.8221T>C p.S2741P | Missense Mutation (SNP) | VAF 62/362 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- ASTN2 | c.3418G>C p.G1140R (on ENST00000313400 / NM_001365069.1; = p.G1089R on NM_014010.5) | Missense Mutation (SNP) | VAF 42/271 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASTN2 | c.2300C>A p.S767Y (on ENST00000313400 / NM_001365069.1; = p.S716Y on NM_014010.5) | Missense Mutation (SNP) | VAF 49/352 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- ATP4A | c.529C>A p.P177T | Missense Mutation (SNP) | VAF 17/267 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- BRD2 | c.2203G>T p.E735* | Nonsense Mutation (SNP) | VAF 251/557 reads (45%) | called by muse, mutect2, varscan2
- BTN3A2 | c.725T>A p.F242Y | Missense Mutation (SNP) | VAF 48/305 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- C14orf39 | c.1382C>G p.P461R | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.483); called by muse, mutect2
- C1QA | c.409A>T p.I137F | Missense Mutation (SNP) | VAF 93/479 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- C5 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACHD1 | c.3487_3488insCCCA p.S1163Tfs*33 | Frame Shift Ins (INS) | VAF 20/191 reads (10%) | called by mutect2, pindel, varscan2
- CACNA1C | c.763C>A p.Q255K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CACNA2D3 | c.1845-2A>C p.X615_splice | Splice Site (SNP) | VAF 69/330 reads (21%) | called by muse, mutect2, varscan2
- CAPN6 | c.738G>T p.W246C | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CASS4 | c.2073C>G p.H691Q | Missense Mutation (SNP) | VAF 76/379 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- CCDC168 | c.16994G>A p.G5665E | Missense Mutation (SNP) | VAF 74/233 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CHD4 | c.3052-2A>T p.X1018_splice (on ENST00000357008 / NM_001363606.2; = p.X1031_splice on NM_001273.5) | Splice Site (SNP) | VAF 44/203 reads (22%) | called by muse, mutect2, varscan2
- CHD4 | c.714G>T p.E238D | Missense Mutation (SNP) | VAF 111/440 reads (25%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CHRNA4 | c.830dup p.C278Vfs*100 | Frame Shift Ins (INS) | VAF 83/568 reads (15%) | called by mutect2, pindel, varscan2
- CLEC2B | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 51/449 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CNTRL | c.3411C>G p.F1137L | Missense Mutation (SNP) | VAF 40/335 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL28A1 | c.830G>T p.G277V | Missense Mutation (SNP) | VAF 25/545 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CR1 | c.2713G>T p.D905Y | Missense Mutation (SNP) | VAF 76/1194 reads (6%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.997); called by muse, mutect2
- CRAMP1 | c.1865G>T p.G622V | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); called by muse, mutect2
- CSF1R | c.944T>A p.V315E | Missense Mutation (SNP) | VAF 44/263 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CSHL1 | c.73G>T p.G25C | Missense Mutation (SNP) | VAF 65/508 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CSMD3 | c.56C>A p.P19H | Missense Mutation (SNP) | VAF 130/432 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CYLD | c.2398A>G p.R800G | Missense Mutation (SNP) | VAF 64/531 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- CYP2C19 | c.1157_1158del p.T386Nfs*11 | Frame Shift Del (DEL) | VAF 39/282 reads (14%) | called by mutect2, pindel, varscan2
- DMRT2 | c.1345G>T p.G449W | Missense Mutation (SNP) | VAF 69/325 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- DNAH10 | c.3816T>A p.D1272E (on ENST00000409039; = p.D1211E on NM_207437.3) | Missense Mutation (SNP) | VAF 50/320 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH6 | c.3539C>A p.A1180E | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- DNHD1 | c.6215G>C p.R2072T | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DOCK3 | c.3139C>A p.P1047T | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.074); called by muse, varscan2
- DSG4 | c.2848A>G p.I950V | Missense Mutation (SNP) | VAF 90/554 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- DUSP26 | c.592C>A p.L198I | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- EPRS1 | c.1262G>T p.W421L | Missense Mutation (SNP) | VAF 41/307 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- EXPH5 | c.1538A>G p.E513G | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2
- FAM83E | c.127G>T p.A43S | Missense Mutation (SNP) | VAF 18/191 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- FBRSL1 | c.2420A>T p.Q807L | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- FCGBP | c.5244G>T p.K1748N | Missense Mutation (SNP) | VAF 111/1032 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); called by muse, mutect2
- FCRL3 | c.658C>A p.P220T | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- FCRL5 | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- FER1L6 | c.3761C>A p.P1254Q | Missense Mutation (SNP) | VAF 97/327 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- FLT4 | c.364G>T p.G122C | Missense Mutation (SNP) | VAF 55/238 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- FPR2 | c.922G>T p.D308Y | Missense Mutation (SNP) | VAF 52/466 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FRG2B | c.586C>A p.Q196K | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.828); called by muse, mutect2
- FSTL5 | c.2035G>A p.V679M | Missense Mutation (SNP) | VAF 78/300 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- GCA | c.627+1G>A p.X209_splice | Splice Site (SNP) | VAF 20/152 reads (13%) | called by muse, mutect2, varscan2
- GLB1L3 | c.1823G>T p.G608V | Missense Mutation (SNP) | VAF 77/332 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GP5 | c.1300G>C p.G434R | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR135 | c.514G>T p.A172S | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GPR137B | c.229T>A p.Y77N | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR149 | c.1021C>A p.L341I | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- GPR156 | c.1704dup p.S569Lfs*27 | Frame Shift Ins (INS) | VAF 18/126 reads (14%) | called by mutect2, pindel, varscan2
- H2BC9 | c.294del p.V99Cfs*48 | Frame Shift Del (DEL) | VAF 193/606 reads (32%) | called by mutect2, pindel, varscan2
- HERC1 | c.1523T>C p.L508P | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- HEXIM2 | c.136A>T p.T46S | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- HNRNPUL1 | c.1184dup p.F397Vfs*10 | Frame Shift Ins (INS) | VAF 384/755 reads (51%) | called by mutect2, pindel, varscan2
- HTT | c.7793T>G p.L2598R | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IFNA16 | c.481C>A p.P161T | Missense Mutation (SNP) | VAF 66/402 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- IFNLR1 | c.1353G>T p.W451C | Missense Mutation (SNP) | VAF 59/313 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- IGKV1-17 | c.305C>A p.P102H | Missense Mutation (SNP) | VAF 35/312 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- IGKV2D-24 | c.274G>T p.A92S | Missense Mutation (SNP) | VAF 69/364 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGLV1-50 | c.242A>G p.D81G | Missense Mutation (SNP) | VAF 18/272 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.554); called by muse, mutect2
- INCENP | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- IZUMO3 | c.105G>T p.L35F | Missense Mutation (SNP) | VAF 103/612 reads (17%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- KANK4 | c.2794G>T p.A932S | Missense Mutation (SNP) | VAF 85/443 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- KCND2 | c.408G>T p.E136D | Missense Mutation (SNP) | VAF 28/211 reads (13%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNH2 | c.3277C>T p.P1093S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- KDM4D | c.548G>T p.G183V | Missense Mutation (SNP) | VAF 27/429 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KDM6B | c.2387_2388insT p.P797Tfs*60 | Frame Shift Ins (INS) | VAF 12/84 reads (14%) | called by pindel, varscan2
- KIF1A | c.980T>C p.M327T | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLF13 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 3/7 reads (43%) | called by muse, mutect2
- KLF14 | c.737A>G p.Y246C | Missense Mutation (SNP) | VAF 33/286 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KLHL29 | c.855_856insT p.T286Yfs*20 | Frame Shift Ins (INS) | VAF 26/178 reads (15%) | called by pindel, varscan2
- LAIR1 | c.320C>A p.P107H | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2
- MAP1B | c.2270C>G p.P757R | Missense Mutation (SNP) | VAF 69/334 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- MAT1A | c.437_438del p.T146Rfs*33 | Frame Shift Del (DEL) | VAF 115/443 reads (26%) | called by mutect2, pindel, varscan2
- MBOAT1 | c.371G>T p.S124I | Missense Mutation (SNP) | VAF 23/231 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- MPHOSPH10 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 65/309 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- MROH2A | c.3982G>C p.E1328Q | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MROH9 | c.1000C>A p.L334I | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- MUC17 | c.7466C>T p.T2489I | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2
- MUC6 | c.2570C>A p.A857D | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- MVK | c.481_482del p.C161Rfs*25 | Frame Shift Del (DEL) | VAF 111/539 reads (21%) | called by pindel, varscan2
- MYOC | c.1127A>T p.Y376F | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYOC | c.686A>C p.K229T | Missense Mutation (SNP) | VAF 34/397 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.205); called by muse, mutect2
- NAT14 | c.340G>C p.A114P | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- NBAS | c.1061G>A p.G354E | Missense Mutation (SNP) | VAF 129/682 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- NDST4 | c.834G>C p.W278C | Missense Mutation (SNP) | VAF 58/272 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NIPBL | c.1427A>T p.E476V | Missense Mutation (SNP) | VAF 110/246 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- NLRP3 | c.1727G>T p.R576L | Missense Mutation (SNP) | VAF 174/897 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- NLRP5 | c.1849A>T p.R617W | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NPAP1 | c.2096C>A p.A699D | Missense Mutation (SNP) | VAF 24/360 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.07); called by muse, mutect2
- NR1H4 | c.249C>A p.Y83* (on ENST00000551379 / NM_001206993.2; = p.Y73* on NM_005123.4) | Nonsense Mutation (SNP) | VAF 98/522 reads (19%) | called by muse, mutect2, varscan2
- NRAP | c.4191G>T p.M1397I (on ENST00000359988 / NM_001322945.2; = p.M1362I on NM_006175.4) | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- OR13F1 | c.828G>T p.L276F | Missense Mutation (SNP) | VAF 50/467 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- OR2T3 | c.41G>T p.S14I | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- OR4C6 | c.789C>A p.H263Q | Missense Mutation (SNP) | VAF 70/457 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- OR4C6 | c.790C>A p.P264T | Missense Mutation (SNP) | VAF 72/456 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- OR4S2 | c.337C>T p.L113F | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- OR5F1 | c.733C>A p.L245M | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5T1 | c.227G>A p.G76D | Missense Mutation (SNP) | VAF 73/363 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- OR9A2 | c.494G>T p.R165L | Missense Mutation (SNP) | VAF 38/431 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2
- OTOG | c.2113G>A p.A705T | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- OTUD5 | c.415G>T p.V139L | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PABPC3 | c.320A>G p.D107G | Missense Mutation (SNP) | VAF 62/300 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, varscan2
- PADI6 | c.508C>A p.Q170K | Missense Mutation (SNP) | VAF 25/239 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- PAFAH1B3 | c.517G>T p.D173Y | Missense Mutation (SNP) | VAF 41/240 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- PCDH10 | c.2824G>T p.E942* | Nonsense Mutation (SNP) | VAF 29/164 reads (18%) | called by muse, mutect2, varscan2
- PCDH11X | c.467C>G p.S156C | Missense Mutation (SNP) | VAF 82/335 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCDH15 | c.3398A>T p.E1133V | Missense Mutation (SNP) | VAF 47/270 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PCDHA4 | c.707dup p.N236Kfs*2 | Frame Shift Ins (INS) | VAF 48/267 reads (18%) | called by mutect2, pindel, varscan2
- PCDHB5 | c.1700G>C p.G567A | Missense Mutation (SNP) | VAF 77/441 reads (17%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDHB9 | c.353G>T p.R118L | Missense Mutation (SNP) | VAF 59/299 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- PDLIM5 | c.364A>T p.N122Y | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- PDZRN4 | c.1765G>T p.G589W (on ENST00000402685 / NM_001164595.2; = p.G331W on NM_013377.4) | Missense Mutation (SNP) | VAF 98/441 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- PEAR1 | c.116C>A p.T39N | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.063); called by mutect2, varscan2
- PEX13 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- PHLDB2 | c.879T>A p.H293Q | Missense Mutation (SNP) | VAF 89/419 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHLDB3 | c.77A>T p.Q26L | Missense Mutation (SNP) | VAF 24/259 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2
- PNCK | c.1012G>T p.G338C (on ENST00000340888 / NM_001366975.1; = p.G421C on NM_001039582.3) | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- POTEF | c.303G>T p.W101C | Missense Mutation (SNP) | VAF 103/767 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- POTEJ | c.2375C>A p.T792N | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.559); called by mutect2, varscan2
- PPP4R3C | c.2272G>T p.E758* | Nonsense Mutation (SNP) | VAF 39/128 reads (30%) | called by muse, mutect2, varscan2
- PRKAR2B | c.407C>A p.P136Q | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- PRPS1L1 | c.362C>G p.A121G | Missense Mutation (SNP) | VAF 85/274 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); called by muse, mutect2, varscan2
- PRR7 | c.79C>A p.L27I | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PRUNE2 | c.6160C>A p.H2054N | Missense Mutation (SNP) | VAF 51/298 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- PTBP1 | c.868G>T p.D290Y | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- PTGS1 | c.1603G>T p.G535W | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRZ1 | c.2591G>T p.G864V | Missense Mutation (SNP) | VAF 35/265 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PUM2 | c.2427G>T p.Q809H | Missense Mutation (SNP) | VAF 50/341 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- PXDNL | c.310T>C p.Y104H | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RASGEF1B | c.1085C>G p.A362G | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- RET | c.3024G>T p.M1008I | Missense Mutation (SNP) | VAF 128/606 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- RFT1 | c.287G>T p.W96L | Missense Mutation (SNP) | VAF 40/370 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- RGS9 | c.861G>A p.L287= | Splice Region (SNP) | VAF 62/382 reads (16%) | called by muse, mutect2, varscan2
- RPL10L | c.46C>A p.P16T | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); called by muse, mutect2
- RPS6KL1 | c.1516C>T p.P506S | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RSF1 | c.2365G>T p.A789S | Missense Mutation (SNP) | VAF 67/450 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- RUSC1 | c.1469C>T p.A490V (on ENST00000368352 / NM_001105203.2; = p.A21V on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/210 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- RYR2 | c.8355G>T p.W2785C | Missense Mutation (SNP) | VAF 38/237 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- RYR2 | c.9230A>T p.Q3077L | Missense Mutation (SNP) | VAF 80/558 reads (14%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2
- RYR2 | c.9232G>T p.G3078C | Missense Mutation (SNP) | VAF 82/568 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SAGE1 | c.1606C>A p.H536N | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- SAP130 | c.282G>T p.E94D | Missense Mutation (SNP) | VAF 69/371 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SCART1 | c.241G>A p.V81I | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.276); called by muse, mutect2
- SDK2 | c.1368G>T p.E456D | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SEMA3C | c.2182G>T p.D728Y | Missense Mutation (SNP) | VAF 116/585 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- SKAP1 | c.70G>T p.G24C | Missense Mutation (SNP) | VAF 49/315 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- SLC1A6 | c.373G>T p.G125W | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2
- SLC35F1 | c.76A>G p.I26V | Missense Mutation (SNP) | VAF 44/211 reads (21%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- SLC4A7 | c.1693A>G p.K565E | Missense Mutation (SNP) | VAF 32/259 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLIT3 | c.3246G>T p.K1082N | Missense Mutation (SNP) | VAF 46/270 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- SMCHD1 | c.5188G>T p.A1730S | Missense Mutation (SNP) | VAF 99/602 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMTN | c.224A>G p.Q75R | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- SNTG1 | c.869G>T p.C290F | Missense Mutation (SNP) | VAF 38/539 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2
- SPDL1 | c.1805G>T p.C602F | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SRP72 | c.1085A>T p.Q362L | Missense Mutation (SNP) | VAF 42/590 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); called by muse, mutect2
- SS18 | c.1065G>T p.Q355H (on ENST00000415083 / NM_001007559.3; = p.Q324H on NM_005637.3) | Missense Mutation (SNP) | VAF 78/510 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- SYN2 | c.762C>G p.N254K | Missense Mutation (SNP) | VAF 62/340 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SYN2 | c.1495C>G p.Q499E | Missense Mutation (SNP) | VAF 44/229 reads (19%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- TACR3 | c.1223C>A p.S408Y | Missense Mutation (SNP) | VAF 181/704 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- TBXT | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 83/381 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- TEX35 | c.587G>A p.G196E | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- TFPI | c.292del p.E98Kfs*16 | Frame Shift Del (DEL) | VAF 38/248 reads (15%) | called by mutect2, pindel, varscan2
- THADA | c.3411G>T p.Q1137H | Missense Mutation (SNP) | VAF 53/312 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- THSD7B | c.4622T>C p.I1541T (on ENST00000272643; = p.I1539T on NM_001316349.2) | Missense Mutation (SNP) | VAF 33/211 reads (16%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM215 | c.639C>A p.S213R | Missense Mutation (SNP) | VAF 37/255 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMEM72 | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- TRIM66 | c.3514T>A p.C1172S | Missense Mutation (SNP) | VAF 77/417 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPM6 | c.1378A>G p.I460V | Missense Mutation (SNP) | VAF 92/624 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- TTN | c.2095G>A p.A699T (on ENST00000591111; = p.A653T on NM_003319.4) | Missense Mutation (SNP) | VAF 53/373 reads (14%) | PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- UNC93A | c.91A>C p.S31R | Missense Mutation (SNP) | VAF 24/254 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UNC93B1 | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- VCAN | c.2943del p.D982Tfs*5 | Frame Shift Del (DEL) | VAF 7/64 reads (11%) | called by mutect2, pindel*
- VPS51 | c.1550dup p.A518Cfs*30 | Frame Shift Ins (INS) | VAF 25/218 reads (11%) | called by mutect2, pindel, varscan2
- VWF | c.6589G>C p.D2197H | Missense Mutation (SNP) | VAF 91/465 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- WHRN | c.2117del p.P706Hfs*33 | Frame Shift Del (DEL) | VAF 29/177 reads (16%) | called by mutect2, pindel, varscan2
- WRAP53 | c.692G>T p.W231L | Missense Mutation (SNP) | VAF 96/482 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZDHHC5 | c.83C>G p.T28R | Missense Mutation (SNP) | VAF 59/242 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZFHX4 | c.9502C>A p.P3168T | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.168); called by mutect2, varscan2
- ZNF225 | c.457T>C p.C153R | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- ZNF330 | c.730G>A p.G244R | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.211); called by muse, mutect2
- ZNF37A | c.615_616del p.C205Wfs*6 | Frame Shift Del (DEL) | VAF 20/203 reads (10%) | called by pindel, varscan2
- ZNF695 | c.296A>T p.E99V | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.013); called by muse, mutect2
- ZNF729 | c.1835C>G p.S612C | Missense Mutation (SNP) | VAF 38/274 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- ZNF773 | c.841G>T p.G281* | Nonsense Mutation (SNP) | VAF 42/380 reads (11%) | called by muse, mutect2, varscan2
- ZNF827 | c.2617A>T p.S873C | Missense Mutation (SNP) | VAF 108/430 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ZNFX1 | c.2840G>T p.R947L | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- A4GNT | c.210C>G p.S70= | Silent (SNP) | VAF 20/169 reads (12%) | catalogued as rs374392631, COSV52629894; called by muse, mutect2, varscan2
- ABCA5 | c.954A>T p.T318= | Silent (SNP) | VAF 14/79 reads (18%) | called by mutect2, varscan2
- ACKR2 | c.783G>T p.V261= | Silent (SNP) | VAF 13/111 reads (12%) | called by muse, mutect2, varscan2
- ACSM4 | c.1005T>C p.Y335= | Silent (SNP) | VAF 100/524 reads (19%) | catalogued as rs1468324043, COSV68067624; called by muse, mutect2
- ALX1 | c.171C>A p.P57= | Silent (SNP) | VAF 57/228 reads (25%) | called by muse, mutect2, varscan2
- ANK3 | c.5994G>T p.R1998= | Silent (SNP) | VAF 23/177 reads (13%) | called by muse, mutect2, varscan2
- ARHGEF26 | c.1032G>T p.L344= | Silent (SNP) | VAF 41/273 reads (15%) | catalogued as rs1192370684; called by muse, mutect2, varscan2
- ARHGEF40 | c.2826G>A p.Q942= | Silent (SNP) | VAF 39/170 reads (23%) | called by muse, mutect2, varscan2
- ASXL3 | c.5253G>T p.T1751= | Silent (SNP) | VAF 41/204 reads (20%) | catalogued as rs910681016, COSV52468534, COSV52473916, COSV52480593; called by muse, mutect2, varscan2
- BCL3 | c.1047G>T p.A349= | Silent (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- BICD2 | c.1971C>G p.A657= | Silent (SNP) | VAF 26/187 reads (14%) | called by muse, mutect2, varscan2
- C16orf92 | c.162C>A p.A54= | Silent (SNP) | VAF 76/309 reads (25%) | called by muse, mutect2, varscan2
- CACNA1C | c.762C>A p.L254= | Silent (SNP) | VAF 13/45 reads (29%) | called by muse, mutect2, varscan2
- CAMTA2 | c.99G>T p.L33= | Silent (SNP) | VAF 57/321 reads (18%) | called by muse, mutect2, varscan2
- CCKBR | c.294C>T p.V98= | Silent (SNP) | VAF 125/497 reads (25%) | called by muse, mutect2, varscan2
- CCKBR | c.543G>C p.L181= | Silent (SNP) | VAF 42/299 reads (14%) | called by muse, mutect2, varscan2
- COMTD1 | c.39G>C p.A13= | Silent (SNP) | VAF 10/89 reads (11%) | called by muse, varscan2
- DCAF12L2 | c.486G>C p.T162= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as COSV63583880; called by muse, mutect2, varscan2
- DCSTAMP | c.282C>A p.G94= | Silent (SNP) | VAF 41/410 reads (10%) | called by muse, mutect2, varscan2
- DDX54 | c.1848G>A p.E616= | Silent (SNP) | VAF 20/210 reads (10%) | called by muse, mutect2
- DSG3 | c.1740C>G p.R580= | Silent (SNP) | VAF 117/575 reads (20%) | called by muse, mutect2, varscan2
- EOMES | c.591C>T p.P197= | Silent (SNP) | VAF 28/145 reads (19%) | catalogued as rs1159168804, COSV55411479; called by muse, mutect2, varscan2
- FAM83C | c.375C>T p.P125= | Silent (SNP) | VAF 18/89 reads (20%) | called by muse, mutect2, varscan2
- FAT3 | c.10116C>T p.P3372= | Silent (SNP) | VAF 20/158 reads (13%) | called by muse, mutect2, varscan2
- FCGBP | c.1974C>T p.P658= | Silent (SNP) | VAF 18/248 reads (7%) | catalogued as rs772376965; called by muse, mutect2
- FCGR3B | c.99A>G p.Q33= | Silent (SNP) | VAF 126/734 reads (17%) | catalogued as rs1305875115; called by muse, mutect2, varscan2
- FCN1 | c.708G>T p.L236= | Silent (SNP) | VAF 20/131 reads (15%) | called by muse, mutect2, varscan2
- FMN2 | c.1125G>T p.P375= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs1314367932; called by muse, mutect2, varscan2
- FNDC3A | c.2061G>T p.L687= (on ENST00000492622 / NM_001079673.2; = p.L631= on NM_014923.5) | Silent (SNP) | VAF 22/63 reads (35%) | called by muse, mutect2, varscan2
- FPR3 | c.847C>T p.L283= | Silent (SNP) | VAF 25/199 reads (13%) | called by muse, mutect2, varscan2
- GABRG2 | c.567G>A p.E189= | Silent (SNP) | VAF 64/392 reads (16%) | catalogued as rs868460983; called by muse, mutect2
- HTT | c.7794G>T p.L2598= | Silent (SNP) | VAF 45/176 reads (26%) | called by muse, mutect2, varscan2
- IER5 | c.636C>T p.P212= | Silent (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- IFNK | c.306C>A p.T102= | Silent (SNP) | VAF 58/340 reads (17%) | catalogued as COSV51783755; called by muse, mutect2, varscan2
- IGKV3-11 | c.93G>T p.L31= | Silent (SNP) | VAF 77/549 reads (14%) | catalogued as rs376010585; called by muse, mutect2, varscan2
- ITPRIPL1 | c.792T>C p.C264= (on ENST00000439118 / NM_001008949.3; = p.C272= on NM_178495.6) | Silent (SNP) | VAF 16/72 reads (22%) | called by muse, mutect2, varscan2
- JPH2 | c.1140G>A p.A380= | Silent (SNP) | VAF 32/212 reads (15%) | catalogued as rs780588148, COSV65905219; called by muse, mutect2, varscan2
- KIAA1671 | c.5100G>A p.E1700= | Silent (SNP) | VAF 18/180 reads (10%) | called by muse, mutect2, varscan2
- KIF19 | c.2226G>T p.P742= | Silent (SNP) | VAF 49/333 reads (15%) | called by muse, mutect2, varscan2
- KLF3 | c.441G>C p.P147= | Silent (SNP) | VAF 90/498 reads (18%) | called by muse, mutect2, varscan2
- KLK14 | c.702C>T p.Y234= | Silent (SNP) | VAF 33/219 reads (15%) | called by muse, mutect2, varscan2
- KNDC1 | c.5175C>T p.F1725= | Silent (SNP) | VAF 69/298 reads (23%) | catalogued as COSV58848527; called by muse, mutect2, varscan2
- LILRB1 | c.2016C>A p.T672= (on ENST00000427581; = p.T621= on NM_006669.6) | Silent (SNP) | VAF 33/231 reads (14%) | catalogued as COSV100206921; called by muse, varscan2
- LINGO4 | c.744C>T p.S248= | Silent (SNP) | VAF 14/115 reads (12%) | called by muse, mutect2, varscan2
- LRP1B | c.12900T>A p.I4300= | Silent (SNP) | VAF 25/269 reads (9%) | catalogued as rs778061176; called by muse, mutect2
- MCOLN2 | c.189G>T p.P63= | Silent (SNP) | VAF 35/320 reads (11%) | called by muse, mutect2, varscan2
- MEI1 | c.3189G>A p.L1063= | Silent (SNP) | VAF 14/109 reads (13%) | called by muse, mutect2, varscan2
- MGAM | c.3853C>A p.R1285= | Silent (SNP) | VAF 13/281 reads (5%) | catalogued as COSV101527709, COSV72074666; called by muse, mutect2
- MRPS33 | c.120G>A p.L40= | Silent (SNP) | VAF 86/590 reads (15%) | called by muse, mutect2, varscan2
- MUC16 | c.28485C>G p.T9495= | Silent (SNP) | VAF 24/192 reads (13%) | catalogued as COSV67479419; called by muse, mutect2, varscan2
- NCKAP5 | c.2430A>T p.S810= | Silent (SNP) | VAF 47/259 reads (18%) | called by muse, mutect2, varscan2
- NEK5 | c.918C>T p.F306= | Silent (SNP) | VAF 30/294 reads (10%) | catalogued as rs1043710691; called by muse, mutect2, varscan2
- NKTR | c.1380T>G p.L460= | Silent (SNP) | VAF 11/83 reads (13%) | called by muse, mutect2, varscan2
- NOS3 | c.507G>A p.E169= | Silent (SNP) | VAF 28/234 reads (12%) | called by muse, mutect2, varscan2
- NPVF | c.318C>A p.A106= | Silent (SNP) | VAF 86/242 reads (36%) | catalogued as COSV56060936; called by muse, mutect2, varscan2
- NRCAM | c.2838T>C p.N946= (on ENST00000379028 / NM_001371124.1; = p.N930= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 34/286 reads (12%) | called by muse, mutect2, varscan2
- NXPE2 | c.315C>A p.T105= | Silent (SNP) | VAF 15/131 reads (11%) | catalogued as COSV100969977, COSV100970056; called by muse, mutect2, varscan2
- OR14K1 | c.138C>A p.L46= | Silent (SNP) | VAF 44/346 reads (13%) | called by muse, mutect2, varscan2
- OR2V1 | c.225C>A p.V75= | Silent (SNP) | VAF 44/187 reads (24%) | called by muse, mutect2, varscan2
- OR51G2 | c.462G>T p.L154= | Silent (SNP) | VAF 38/150 reads (25%) | called by muse, mutect2, varscan2
- OR52J3 | c.207C>A p.S69= | Silent (SNP) | VAF 90/469 reads (19%) | called by muse, mutect2, varscan2
- OR6M1 | c.135C>A p.S45= | Silent (SNP) | VAF 38/374 reads (10%) | called by muse, mutect2
- PCCA | c.999G>T p.G333= | Silent (SNP) | VAF 68/324 reads (21%) | called by muse, mutect2
- PCDH7 | c.2106G>T p.R702= | Silent (SNP) | VAF 62/384 reads (16%) | called by muse, mutect2, varscan2
- PIK3C2B | c.1029G>C p.L343= | Silent (SNP) | VAF 27/158 reads (17%) | catalogued as rs1463973147; called by muse, varscan2
- RAD54L | c.1638G>A p.T546= | Silent (SNP) | VAF 75/654 reads (11%) | catalogued as rs751660537, COSV58439645; called by muse, mutect2, varscan2
- RFX6 | c.300G>C p.A100= | Silent (SNP) | VAF 40/497 reads (8%) | catalogued as COSV100264137, COSV60585692; called by muse, mutect2
- RFX6 | c.2118G>T p.V706= | Silent (SNP) | VAF 42/529 reads (8%) | called by muse, mutect2
- RGS19 | c.570G>A p.R190= | Silent (SNP) | VAF 15/184 reads (8%) | called by muse, mutect2
- RUNX3 | c.114G>T p.A38= | Silent (SNP) | VAF 19/99 reads (19%) | called by muse, mutect2, varscan2
- RYR3 | c.3579G>T p.L1193= | Silent (SNP) | VAF 83/237 reads (35%) | called by muse, mutect2, varscan2
- SERPINB3 | c.453G>T p.V151= | Silent (SNP) | VAF 68/346 reads (20%) | catalogued as COSV52191775; called by muse, mutect2, varscan2
- SIRT6 | c.141G>T p.V47= | Silent (SNP) | VAF 18/112 reads (16%) | called by muse, mutect2, varscan2
- SLC22A12 | c.948C>A p.T316= | Silent (SNP) | VAF 44/121 reads (36%) | called by muse, mutect2, varscan2
- SLC38A4 | c.1230C>A p.I410= | Silent (SNP) | VAF 35/272 reads (13%) | catalogued as COSV56966186; called by muse, mutect2, varscan2
- SLC7A9 | c.1242C>T p.P414= | Silent (SNP) | VAF 60/816 reads (7%) | catalogued as rs536084711, COSV50083826; called by muse, mutect2
- SMG6 | c.2637G>T p.G879= | Silent (SNP) | VAF 55/248 reads (22%) | catalogued as rs758996856; called by muse, mutect2, varscan2
- SMYD1 | c.1419C>G p.V473= | Silent (SNP) | VAF 32/181 reads (18%) | called by muse, mutect2, varscan2
- TACR3 | c.1224C>A p.S408= | Silent (SNP) | VAF 183/714 reads (26%) | catalogued as COSV59198652; called by muse, mutect2, varscan2
- TERB2 | c.381C>G p.T127= | Silent (SNP) | VAF 33/127 reads (26%) | called by muse, mutect2, varscan2
- TSHZ1 | c.1998G>T p.L666= (on ENST00000580243 / NM_001308210.2; = p.L621= on NM_005786.6) | Silent (SNP) | VAF 24/122 reads (20%) | called by muse, mutect2, varscan2
- TTLL3 | c.876T>C p.T292= | Silent (SNP) | VAF 31/258 reads (12%) | catalogued as rs1403721491; called by muse, mutect2, varscan2
- ZC3H7B | c.1437G>T p.V479= | Silent (SNP) | VAF 10/81 reads (12%) | called by muse, mutect2, varscan2
- ZFHX3 | c.1509G>T p.L503= | Silent (SNP) | VAF 29/178 reads (16%) | called by muse, mutect2, varscan2
- ZNF729 | c.1836C>A p.S612= | Silent (SNP) | VAF 38/272 reads (14%) | catalogued as COSV100675546; called by muse, mutect2, varscan2
- ABCC13 | n.3368A>C | RNA (SNP) | VAF 48/166 reads (29%) | called by muse, varscan2
- AC002511.3 | n.405G>T | RNA (SNP) | VAF 192/343 reads (56%) | called by muse, mutect2, varscan2
- AC005670.2 | chr17:47049930 C>A | 3'Flank (SNP) | VAF 81/1757 reads (5%) | called by muse, mutect2
- AC136604.1 | chr5:179652311 G>C | 3'Flank (SNP) | VAF 107/533 reads (20%) | called by muse, varscan2
- ACSF3 | c.*695G>T | 3'UTR (SNP) | VAF 16/112 reads (14%) | catalogued as rs567337830; called by muse, mutect2, varscan2
- ACTN1 | c.1235-17G>A | Intron (SNP) | VAF 7/77 reads (9%) | called by muse, mutect2
- ADGB | c.4818+5458A>T | Intron (SNP) | VAF 50/470 reads (11%) | called by muse, mutect2
- AICDA | c.427+12C>A | Intron (SNP) | VAF 73/337 reads (22%) | catalogued as COSV99984389; called by muse, mutect2, varscan2
- AL590867.2 | n.418G>T | RNA (SNP) | VAF 46/203 reads (23%) | called by muse, mutect2, varscan2
- ANAPC5 | c.207+1023G>C | Intron (SNP) | VAF 26/147 reads (18%) | called by muse, mutect2, varscan2
- ASIC1 | c.559-3190T>C | Intron (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2, varscan2
- ATG16L1 | c.954+1179G>T | Intron (SNP) | VAF 39/259 reads (15%) | called by muse, mutect2, varscan2
- ATP13A2 | c.1542+18del | Intron (DEL) | VAF 28/191 reads (15%) | called by mutect2, pindel, varscan2
- C3orf52 | c.*180A>T | 3'UTR (SNP) | VAF 53/249 reads (21%) | called by muse, mutect2, varscan2
- CASTOR1 | c.113+17G>T | Intron (SNP) | VAF 27/188 reads (14%) | catalogued as rs1165657684; called by muse, mutect2, varscan2
- COG4 | c.1062-43G>T | Intron (SNP) | VAF 29/178 reads (16%) | called by muse, mutect2, varscan2
- DCAF13 | chr8:103415181 T>A | 5'Flank (SNP) | VAF 19/62 reads (31%) | catalogued as COSV52568744; called by muse, mutect2, varscan2
- DNAAF3 | c.-85A>T | 5'UTR (SNP) | VAF 25/153 reads (16%) | called by muse, mutect2, varscan2
- DOCK4 | c.2736+3910T>C | Intron (SNP) | VAF 51/294 reads (17%) | called by muse, mutect2, varscan2
- DOK3 | c.66+10C>A | Intron (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
- FAM74A3 | n.79G>C | RNA (SNP) | VAF 95/923 reads (10%) | catalogued as rs370250075; called by muse, mutect2, varscan2
- FGF23 | c.212-27C>A | Intron (SNP) | VAF 116/476 reads (24%) | called by muse, mutect2, varscan2
- GPAM | c.2312-36G>T | Intron (SNP) | VAF 47/429 reads (11%) | called by muse, mutect2, varscan2
- GPATCH8 | c.*1365G>T | 3'UTR (SNP) | VAF 53/389 reads (14%) | called by muse, mutect2, varscan2
- GRM5 | c.661+62428C>T | Intron (SNP) | VAF 28/164 reads (17%) | called by muse, mutect2, varscan2
- GVINP1 | n.4379T>A | RNA (SNP) | VAF 60/341 reads (18%) | called by muse, mutect2, varscan2
- IQCG | c.-8A>G | 5'UTR (SNP) | VAF 15/122 reads (12%) | catalogued as rs896001911; called by muse, mutect2, varscan2
- JPH3 | c.2167-664C>A | Intron (SNP) | VAF 23/138 reads (17%) | called by muse, mutect2, varscan2
- KLF10 | c.-22G>C | 5'UTR (SNP) | VAF 19/190 reads (10%) | called by muse, mutect2, varscan2
- LGALS9C | c.131+43C>G | Intron (SNP) | VAF 132/229 reads (58%) | called by muse, mutect2, varscan2
- LINC00303 | n.178T>A | RNA (SNP) | VAF 34/180 reads (19%) | called by muse, mutect2, varscan2
- LINC00602 | n.759A>G | RNA (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
- LINC00955 | n.725C>A | RNA (SNP) | VAF 76/346 reads (22%) | catalogued as rs1439109838; called by muse, mutect2, varscan2
- LINC02876 | n.158G>T | RNA (SNP) | VAF 27/195 reads (14%) | catalogued as rs533710513; called by muse, mutect2, varscan2
- LINC02876 | n.515A>C | RNA (SNP) | VAF 35/182 reads (19%) | called by muse, mutect2, varscan2
- LRP5L | n.644C>T | RNA (SNP) | VAF 46/335 reads (14%) | called by muse, mutect2, varscan2
- LRR1 | c.*132A>G | 3'UTR (SNP) | VAF 14/131 reads (11%) | catalogued as COSV100023347; called by muse, mutect2, varscan2
- LSP1 | c.53+13392del | Intron (DEL) | VAF 8/38 reads (21%) | called by mutect2, pindel, varscan2
- MARCHF1 | c.-322-85920C>G | Intron (SNP) | VAF 55/544 reads (10%) | called by muse, mutect2, varscan2
- MARCHF8 | c.242+883G>T | Intron (SNP) | VAF 30/187 reads (16%) | catalogued as COSV100165758; called by muse, mutect2, varscan2
- MIR1324 | n.7G>T | RNA (SNP) | VAF 31/398 reads (8%) | catalogued as rs1221878837; called by muse, mutect2
- MUC19 | n.5209G>T | RNA (SNP) | VAF 58/341 reads (17%) | called by muse, mutect2, varscan2
- OR5P1P | n.347G>T | RNA (SNP) | VAF 46/177 reads (26%) | called by muse, mutect2, varscan2
- PTPRD | c.3989-529C>A | Intron (SNP) | VAF 22/137 reads (16%) | called by muse, mutect2, varscan2
- PTPRQ | chr12:80435078 C>A | 5'Flank (SNP) | VAF 37/174 reads (21%) | called by muse, mutect2, varscan2
- PYROXD1 | c.-63C>T | 5'UTR (SNP) | VAF 38/217 reads (18%) | catalogued as rs1031118605; called by muse, mutect2
- RAX | c.-1C>A | 5'UTR (SNP) | VAF 16/86 reads (19%) | called by muse, varscan2
- RNF217-AS1 | n.522G>T | RNA (SNP) | VAF 15/195 reads (8%) | called by muse, mutect2
- SEC14L3 | c.55-608G>T | Intron (SNP) | VAF 10/57 reads (18%) | called by muse, mutect2, varscan2
- SMOC2 | c.-43C>G | 5'UTR (SNP) | VAF 42/165 reads (25%) | called by muse, mutect2, varscan2
- STXBP2 | c.1452+36C>T | Intron (SNP) | VAF 24/168 reads (14%) | catalogued as rs1239552500; called by muse, mutect2, varscan2
- SYNGR2 | c.*4G>C | 3'UTR (SNP) | VAF 22/146 reads (15%) | called by muse, mutect2
- SYNPO | chr5:150656449 G>A | 3'Flank (SNP) | VAF 35/115 reads (30%) | called by muse, mutect2, varscan2
- SYNRG | c.78-102C>T | Intron (SNP) | VAF 49/308 reads (16%) | called by muse, mutect2, varscan2
- TNNT3 | c.116-29G>T | Intron (SNP) | VAF 47/286 reads (16%) | called by muse, mutect2, varscan2
- TTN | c.10360+3112G>T | Intron (SNP) | VAF 34/497 reads (7%) | called by muse, mutect2
- TTYH1 | c.126+1220G>T | Intron (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2
- TYMP | c.417+12C>G | Intron (SNP) | VAF 51/343 reads (15%) | called by muse, mutect2, varscan2
- ZNF160 | c.271+717C>T | Intron (SNP) | VAF 24/302 reads (8%) | called by muse, mutect2
- ZNF300P1 | n.1415C>A | RNA (SNP) | VAF 40/303 reads (13%) | called by muse, mutect2, varscan2
